Surgical pathology report (de-identified scan), TCGA case TCGA-28-1747, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1747-01C (Primary Tumor).

CGA-28-1747

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, LEFT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, LEFT PARIETAL SUPERIOR, BIOPSY:

- Cortex and white matter

C. BRAIN, LEFT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED]

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with [REDACTED]

HISTORY: Benign neoplasm of the brain

MICROSCOPIC:

As best revealed on slide C1 this high-grade astrocytoma in addition to densely cellular proliferation of pleomorphic tumor cells as revealed on a previous excisional biopsy [REDACTED] now also contains foci of microvascular proliferation and necrosis with palisading. The findings are of glioblastoma multiforme. Slide B1 shows cortex and underlying white matter with no definitive tumor cells.

IMMUNOSTAINS:

Laminin beta 1 (C1): Up-regulated (3+ in endothelial cells)

Laminin beta 2 (9/421) (C1): Up-regulation in ectatic and smaller capillaries with down-regulation in some of the foci with microvascular proliferation

GROSS:

A. LEFT PARIETAL TUMOR

Patient Case(s): [REDACTED]

Source: NCI Genomic Data Commons file 83ce7b92-a077-49c7-bdc8-d46699ab2d59 (TCGA-28-1747.F1F20DD1-F50B-4F3C-A7FA-8307F08D0757.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).